Somatic mutation profile of tumor specimen BA3410D (aliquot aq-BA3410D) from BEATAML1.0 case 2695, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,307 days).
Specimen BA3410D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e65e9163-462e-4ecb-af78-3a5877e8ba16.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3256D (Solid Tissue Normal), aliquot aq-BA3256D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a32ca567-feda-4915-a735-62c0055a5c55

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 48/79 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IQCN | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200482859; called by muse, mutect2
- ADGRG6 | c.663_677del p.Y222_I226del | In Frame Del (DEL) | VAF 82/244 reads (34%) | called by mutect2, varscan2
- TFDP3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2, varscan2
